Somatic mutation profile of cancer-model specimen HCM-BROD-0423-C71-85D (3D Neurosphere, passage 10; aliquot HCM-BROD-0423-C71-85D-01D-A85E-36), derived from the primary tumor of HCMI case HCM-BROD-0423-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.9 years (13,854 days).
Specimen HCM-BROD-0423-C71-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a9f1bf8-94f5-44a3-9e66-c6ce72a9075c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0423-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0423-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04753205-6df9-446e-bdf3-dc72bf388284

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Frame Shift Del 4, Nonsense Mutation 1, 3'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP3 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 106/188 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as rs199608986, COSV60876072; called by muse, varscan2
- CRNN | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55120837; called by muse, varscan2
- EIF2B5 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 218/440 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.299); catalogued as COSV56605972; called by mutect2, varscan2
- FAM102A | c.856C>T p.R286W (on ENST00000373095 / NM_001035254.3; = p.R144W on NM_203305.2) | Missense Mutation (SNP) | VAF 248/738 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs370993152; called by muse, varscan2
- FXN | c.109G>T p.D37Y (on ENST00000377270; = p.D112Y on NM_000144.5) | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1239243428; called by mutect2, varscan2
- GZMA | c.349del p.L117Ffs*4 | Frame Shift Del (DEL) | VAF 122/278 reads (44%) | catalogued as rs773819120; called by mutect2, pindel, varscan2
- HHIPL2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 134/251 reads (53%) | catalogued as rs779253171, COSV58563608, COSV58567693; called by muse, mutect2, varscan2
- MS4A6E | c.327C>G p.D109E | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.25); catalogued as rs752038447; called by muse, mutect2, varscan2
- OR2H1 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs147827730; called by muse, varscan2
- OR9H1P | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs1349492735; called by muse, varscan2
- PLA2G4A | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV66554660; called by muse, varscan2
- PMCH | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as COSV59672281; called by muse, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 155/166 reads (93%) | catalogued as rs146650273; called by pindel, varscan2
- RAMP3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 255/769 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.337); catalogued as rs778074274, COSV54246431; called by muse, varscan2
- RBM27 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 168/354 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.982); catalogued as rs371826086; called by muse, varscan2
- SPATA31E1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.231); catalogued as COSV57794255; called by muse, mutect2
- STAG2 | c.2286del p.K763Nfs*3 | Frame Shift Del (DEL) | VAF 102/143 reads (71%) | catalogued as COSV54354371; called by mutect2, pindel, varscan2
- TAF11L13 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs140697354; called by muse, varscan2
- TP53I11 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57534263; called by muse, varscan2
- TRPC4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 138/282 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58993518; called by muse, mutect2, varscan2
- TTLL10 | c.1304A>C p.H435P (on ENST00000379289 / NM_001130045.2; = p.H362P on NM_153254.3) | Missense Mutation (SNP) | VAF 223/445 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs772622013; called by muse, mutect2, varscan2
- AKAP11 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 14/493 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- AKAP13 | c.4885G>A p.E1629K (on ENST00000394518 / NM_007200.5; = p.E1633K on NM_006738.6) | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- AMY1C | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ARHGAP33 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 152/338 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CLEC7A | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, varscan2
- CTNND1 | c.2312C>T p.S771F (on ENST00000399050 / NM_001085458.2; = p.S765F on NM_001331.3) | Missense Mutation (SNP) | VAF 167/598 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENOX2 | c.308G>C p.C103S (on ENST00000338144 / NM_001382520.1; = p.C74S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FXN | c.110A>G p.D37G (on ENST00000377270; = p.D112G on NM_000144.5) | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FZD10 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 348/720 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GIGYF2 | c.3220T>G p.S1074A | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GTF2E1 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.209); called by muse, varscan2
- HAPLN1 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.175A>C p.K59Q (on ENST00000354667 / NM_031243.3; = p.K47Q on NM_002137.4) | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ITGB8 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- KIAA0408 | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 130/162 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFS1 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.479); called by muse, mutect2
- OR52E6 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 142/271 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, varscan2
- PHF3 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLD1 | c.721T>G p.C241G | Missense Mutation (SNP) | VAF 73/357 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PLS1 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBCK1 | c.19A>C p.K7Q (on ENST00000356286 / NM_031229.4; = p.E13A on NM_006462.6) | Missense Mutation (SNP) | VAF 260/548 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- RENBP | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 159/162 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- RGPD4 | c.2921A>G p.D974G | Missense Mutation (SNP) | VAF 125/506 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); called by muse, varscan2
- RYR1 | c.10825-1G>A p.X3609_splice | Splice Site (SNP) | VAF 168/366 reads (46%) | called by muse, mutect2, varscan2
- SNRNP70 | c.885T>G p.S295R | Missense Mutation (SNP) | VAF 330/717 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TMEM232 | c.611del p.F204Sfs*20 | Frame Shift Del (DEL) | VAF 65/197 reads (33%) | called by mutect2, pindel, varscan2
- TMEM236 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TNS3 | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- UGT2B15 | c.1320A>C p.K440N | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR87 | c.7679G>T p.G2560V | Missense Mutation (SNP) | VAF 85/454 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF91 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 161/318 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ACOXL | c.1740G>A p.P580= (on ENST00000676595; = p.P550= on NM_001142807.4) | Silent (SNP) | VAF 355/725 reads (49%) | called by muse, mutect2, varscan2
- AJAP1 | c.564C>T p.D188= | Silent (SNP) | VAF 295/606 reads (49%) | catalogued as COSV65453182; called by muse, varscan2
- ATP5F1C | c.15G>A p.A5= | Silent (SNP) | VAF 18/548 reads (3%) | called by muse, mutect2
- DNAH1 | c.4869G>T p.L1623= | Silent (SNP) | VAF 15/316 reads (5%) | called by muse, mutect2
- ERV3-1 | c.828C>T p.F276= | Silent (SNP) | VAF 207/608 reads (34%) | catalogued as rs761270010, COSV104391678; called by muse, mutect2, varscan2
- FNDC1 | c.774C>T p.D258= | Silent (SNP) | VAF 126/126 reads (100%) | catalogued as rs765767174; called by muse, varscan2
- FNIP1 | c.786C>T p.L262= | Silent (SNP) | VAF 111/251 reads (44%) | called by muse, mutect2, varscan2
- LEXM | c.516G>A p.K172= | Silent (SNP) | VAF 124/261 reads (48%) | called by muse, mutect2, varscan2
- MEF2C | c.891C>T p.S297= | Silent (SNP) | VAF 51/347 reads (15%) | catalogued as rs755665375; called by muse, mutect2, varscan2
- NLRP5 | c.3351C>T p.A1117= | Silent (SNP) | VAF 155/435 reads (36%) | catalogued as COSV66765913; called by muse, mutect2, varscan2
- SGSM1 | c.2862G>A p.T954= (on ENST00000400359 / NM_001039948.4; = p.T893= on NM_133454.3) | Silent (SNP) | VAF 126/260 reads (48%) | catalogued as rs1038290904, COSV63082825; called by muse, varscan2
- SHANK2 | c.1371C>T p.P457= | Silent (SNP) | VAF 318/647 reads (49%) | catalogued as rs782397098, COSV53612223; ClinVar: likely benign; called by muse, varscan2
- SIK3 | c.1650C>T p.N550= (on ENST00000445177 / NM_001366686.2; = p.N556= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 199/430 reads (46%) | called by muse, mutect2, varscan2
- SOST | c.378A>T p.R126= | Silent (SNP) | VAF 406/760 reads (53%) | called by muse, varscan2
- TADA1 | c.559C>T p.L187= | Silent (SNP) | VAF 94/218 reads (43%) | called by muse, varscan2
- TMPRSS9 | c.957C>T p.N319= (on ENST00000648592; = p.N285= on NM_182973.2) | Silent (SNP) | VAF 298/651 reads (46%) | catalogued as rs368841376; called by muse, varscan2
- UGT2A3 | c.231C>G p.V77= | Silent (SNP) | VAF 216/424 reads (51%) | called by muse, varscan2
- UNC13B | c.762-6348G>A | Intron (SNP) | VAF 110/277 reads (40%) | called by muse, varscan2
- XIRP2 | c.*492A>G | 3'UTR (SNP) | VAF 148/296 reads (50%) | called by muse, varscan2
